Gene-level copy-number profile of tumor specimen TCGA-EM-A3AI-01A from TCGA case TCGA-EM-A3AI, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 68.0 years (24,820 days).
Specimen TCGA-EM-A3AI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.5d7a28db-af75-4652-ad55-2c806eb82afd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EM-A3AI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3bbc992b-ea29-402e-9e97-3c644a2b3aa6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 41,421; copy number 5: 15,385; copy number 8: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EM-A3AI-01A-11D-A201-01): tumor purity 0.78, ploidy 2.34, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18,399 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–181,342,213, 2,985 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 8 (broad region; genes not listed).
- chr12:66,767–133,214,832, 3,050 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–90,222,851, 2,560 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–83,095,122, 3,047 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
